Gene-level copy-number profile of tumor specimen MP2PRT-PAVAGF-TMP1-A from MP2PRT case MP2PRT-PAVAGF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (938 days).
Specimen MP2PRT-PAVAGF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file beee01b5-e916-43ad-85b8-5d78c63ff96d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVAGF-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/0dde07b2-03c3-4777-8a8d-8fdc9fe64189

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 134; copy number 1: 121; copy number 2: 58,084; copy number 3: 55; copy number 4: 3.

Homozygous deletions (total copy number 0; autosomes only): 134 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:226,445,937–226,446,292, 1 gene: RN7SKP165.
- chr14:22,483,004–22,490,553, 6 genes (within-gene range 0–3): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr14:105,672,308–106,481,706, 125 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 121. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
